Surgical pathology report (de-identified scan), TCGA case TCGA-MA-AA3Z, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-MA-AA3Z-01A (Primary Tumor).

[page 1 of 3]
Results

SURGICAL PATHOLOGY

Entry Date

Component Results

Component

Surgical Pathology
(note)

Hospital
Location

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

ICD-O-3
Carcinoma, squamous cell NOS
Site Cervix NOS C53.9
4/11/14

PATHOLOGIC DIAGNOSIS

A. UTERINE CERVIX, DESIGNATED AS "A", BIOPSY:

- SUPERFICIAL FRAGMENTS OF SQUAMOUS CELL CARCINOMA WITH PAPILLARY ARCHITECTURE
- SEE COMMENT

B. UTERINE CERVIX, DESIGNATED AS "B", BIOPSY:

- SUPERFICIAL FRAGMENTS OF SQUAMOUS CELL CARCINOMA WITH PAPILLARY ARCHITECTURE
- SEE COMMENT

"I have personally reviewed the resident's gross description and all specimen preparations and have personally issued this report."

Comment

The cervical biopsies, designated as A and B, have superficial fragments of squamous cell carcinoma with a papillary architecture. No underlying stroma is identified to assess for tumor extent. Clinical correlation is recommended.

The results were given to
hours.

by telephone on at

Dr. has reviewed the case and agrees with the above diagnosis.

Pertinent Clinical Information

Pertinent History/Operative Findings: Squamous cell carcinoma on recent cervical biopsy

Specimen Material: Cervix biopsy x 2.

Gross Description

The specimen is received in two parts, each labeled with the patient's name and medical record number.

Part A: Received in formalin and labeled with the patient's name and "CERVICAL BIOPSY" on the requisition is a tan-pink papilliferous portion of soft tissue measuring 1.5 x 1.5 x 0.3 cm. The specimen is submitted in toto in cassette A1.

by

[page 2 of 3]
Part B: Received fresh and labeled with the patient's name and "CERVIX BIOPSY" are multiple tan-pink to tan-red portions of soft tissue and adherent clotted blood measuring 3.5 x 2.0 x 1.0 cm. Representative sections are submitted to the _____ and the remaining tissue is submitted in its entirety in cassettes B1 and B2.

Pathologists' Assistant

Microscopic Description
A-B: Performed.

Electronically Signed Out

Staff Pathologist

Result History

SURGICAL PATHOLOGY (Order # _____) on _____ - Order Result History Report.

Lab Information

Resulting Lab

Order Information

Order Date

Order Time

Result Information

Result Date and Time

Status
Final result

Priority
Routine

Received Date/Time

Received Date

Received Time

Order Providers

Authorizing Provider

Encounter Provider

Encounter

[View Encounter](#)

Order

SURGICAL PATHOLOGY

(Order # _____)

Administration Details

No Administrations
Recorded

Order Information

Order Date/Time

Release Date/Time
None

Start Date/Time

End Date/Time
None

Order Details

Frequency
None

Duration
None

Priority
Routine

Order Class
Normal

Quantity

Ordering Quantity

[page 3 of 3]
Collection Information

Collection Date

Collection Time

Resulting Agency

Provider Information

Ordering User

Authorizing Provider

Attending Provider(s)

Order-Level Documents:

There are no order-level documents.

Encounter[View Encounter](#)**Orders Needing Specimen Collection**

** None **

Source: NCI Genomic Data Commons file 21d904b4-ecce-47d7-8eb7-10db76f6ec48 (TCGA-MA-AA3Z.9CE46816-BE2F-46EA-880C-709BE2D40A1A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).